Somatic mutation profile of tumor specimen TCGA-2G-AAGZ-01A (aliquot TCGA-2G-AAGZ-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGZ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 27.8 years (10,157 days).
Specimen TCGA-2G-AAGZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ed519d3-cd51-490b-b9e3-4e8baa9e4846.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGZ-10A (Blood Derived Normal), aliquot TCGA-2G-AAGZ-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bef96386-8427-4e33-bc6d-ee7855cc9e84

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 1, RNA 1, Frame Shift Del 1, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA2 | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1240049476; called by muse, mutect2, varscan2
- EP300 | c.5702C>T p.A1901V | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.307); catalogued as COSV54342255; called by muse, mutect2
- TPST2 | c.691_693del p.E231del | In Frame Del (DEL) | VAF 10/106 reads (9%) | catalogued as rs1412009345; called by mutect2, pindel
- CDH3 | c.2183_2184insA p.V729Gfs*5 | Frame Shift Ins (INS) | VAF 16/144 reads (11%) | called by mutect2, varscan2
- COG1 | c.2806G>T p.V936F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- GON4L | c.4624G>T p.D1542Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HERC1 | c.14305_14306del p.R4769Gfs*19 | Frame Shift Del (DEL) | VAF 16/172 reads (9%) | called by mutect2, pindel
- HIKESHI | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.177); called by muse, mutect2
- SRCAP | c.4066C>G p.P1356A | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); called by muse, mutect2
- TTC27 | c.1916G>A p.S639N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CACNA2D1 | c.768T>A p.I256= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- EIF3B | c.1045C>T p.L349= | Silent (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- HCN3 | c.2085T>C p.G695= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- KRT37 | c.930C>T p.S310= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as rs147477673; called by muse, mutect2
- LRRC66 | c.2049C>T p.N683= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- SH3D21 | c.753G>A p.V251= (on ENST00000453908 / NM_001162530.2; = p.V140= on NM_024676.5) | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1206949701; called by muse, mutect2, varscan2
- GRM8 | c.2677+32G>C | Intron (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- NAMPTP1 | n.976C>A | RNA (SNP) | VAF 24/420 reads (6%) | called by muse, mutect2
- VSIG4 | chrX:66018968 C>G | 3'Flank (SNP) | VAF 26/156 reads (17%) | called by muse, mutect2, varscan2
